Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A3AR, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A3AR-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Consultation Report

Patient Name:

MRN:

DOB:

Gender:

HCN:

Ordering MD:

Copy To:

Service:

Visit #:

Location:

Facility:

Accession #

Collected:

Received:

Reported:

Specimen(s) Re:

1. Thyroid: total thyroid, stitch mark left superior pole

Diagnosis

Multifocal papillary carcinoma, dominant 1.2 cm, widely invasive classical variant, left: Thyroid

Metastatic papillary thyroid carcinoma: Lymph node, 1, left

-Total thyroidectomy specimen. See Comment.

Comment

The dominant tumor is a widely invasive classical variant with multiple tumor deposits in the left lobe. There are many regions which are highly suspicious for lymphatic invasion, but there is no definitive evidence of vascular invasion. There is one lymph node on the left side which is nearly completely replaced by metastatic papillary thyroid carcinoma.

Synoptic Data

Procedure: Total thyroidectomy
Received: Fresh
Specimen Integrity: Intact
Specimen Size: Right lobe:
5.0 cm
2.7 cm
2.0 cm
Left lobe:
5.1 cm
3.0 cm
2.2 cm
Isthmus +/- pyramidal lobe:
5.5 cm
1.5 cm
1.3 cm
Specimen Weight: 34.9 g
Tumor Focality: Multifocal, bilateral
----- DOMINANT TUMOR -----

1CD-0-3

carcinoma, papillary, thyroid 8280/3

Site: thyroid, NOS C73.9

hw
10/21/11

Reviewed Initials: FM Date Reviewed: 9/22/11		

[page 2 of 2]
Tumor Laterality: Left lobe
Tumor Size: Greatest dimension: 1.2cm
Additional dimension: 1.1 cm
Additional dimension: 0.7 cm
Histologic Type: Papillary carcinoma, classical (usual)
Classical (papillary) architecture
Classical cytormorphology
Histologic Grade: Not applicable
Margins: Margins uninvolved by carcinoma
Distance of invasive carcinoma to closest margin: 0.1mm
Tumor Capsule: Partially encapsulated
Tumor Capsular Invasion: Present, extent widely invasive
Lymph-Vascular Invasion: Indeterminate
Perineural Invasion: Not identified
Extrathyroidal Extension: Not identified
----- SECOND TUMOR -----
Tumor Laterality: Right lobe
Tumor Size: Greatest dimension: 0.7cm
Histologic Type: Papillary carcinoma, classical (usual)
Papillary carcinoma, microcarcinoma (occult, small or microscopic) variant
Classical (papillary) architecture
Classical cytormorphology
Histologic Grade: Not applicable
Margins: Margins uninvolved by carcinoma
Tumor Capsule: Partially encapsulated
Tumor Capsular Invasion: Present, extent minimal
Lymph-Vascular Invasion: Not identified
Perineural Invasion: Not identified
Extrathyroidal Extension: Not identified
TNM Descriptors: m (multiple primary tumors)
Primary Tumor (pT): pT1b: Tumor more than 1 cm but not more than 2 cm in greatest dimension, limited to the thyroid
Regional Lymph Nodes (pN): pN1a: Nodal metastases to Level VI (pretracheal, paratracheal and prelaryngeal/Delphian) lymph nodes
Number of regional lymph nodes examined: 1
Number of regional lymph nodes involved: 1
Distant Metastasis (pM): Not applicable
Additional Pathologic Findings: Other: Multiple additional papillary microcarcinomas identified in the right lobe and left lobe.

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

Electronically verified by:
D

Gross Description

1. The specimen labeled with the patient's name and as "total thyroid stitch marks left superior pole" consists of a thyroid gland that is oriented with a suture and weighs 34.9 g. The right lobe measures 5.0 cm SI x 2.7 cm ML x 2.0 cm AP, the left lobe measures 5.1 cm SI x 3.0 cm ML x 2.2 cm AP and the isthmus measures 5.5 cm SI x 1.5 cm ML x 1.3 cm AP. The external surfaces have fibrous adhesions. No parathyroid glands and/or lymph nodes are identified grossly. The external surface is painted with Silver nitrate. The left lobe contains a well delineated nodule that measures 0.7 cm SI x 1.2 cm ML x 1.1 cm AP. The remainder of the thyroid tissue is grossly normal. Sections of the nodule and normal tissue are stored frozen. The remainder of the specimen is submitted as follows:
A-L right lobe, superior to inferior

Source: NCI Genomic Data Commons file 229f7e93-d284-4203-918e-992fe96c8267 (TCGA-EM-A3AR.19DE70E7-8F9B-4B4F-ABE5-C9D734165AF7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).